MMRF case MMRF_1252 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e60b6e4c-852a-4d05-9619-5eb36788edf1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Dead; Days to death: 463 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.3 years (28,229 days); ISS stage: II; Days to last known disease status: 463 days (1.3 years); Days to last follow up: 463 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 45 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 45 days; Days to treatment end: 333 days.
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 338 days; Days to treatment end: 366 days (1.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 463.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.038 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.8 mg/dL; Immunoglobulin G 62.2 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.99 µg/mL; Lactate Dehydrogenase 4.58 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.9 mmol/L; Albumin 26 g/L; Total Protein 10 g/dL; Glucose 6.55 mmol/L; C-Reactive Protein 0.04 mg/dL.
- Day 101 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5 mg/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 5.5 mmol/L.
- Day 172: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.464 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 29.8 mg/dL; Immunoglobulin G 5.16 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 13.4 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.01 mmol/L.
- Day 289 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.627 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.21 mg/dL; Immunoglobulin G 5.81 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 5.75 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.56 mmol/L.
- Day 400 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.049 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 88.1 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 42.1 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.9 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day 1: Weight: 58 kg; Height: 163 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1252_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1252_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
